HCMI case HCM-CSHL-0366-C50 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Epithelial Neoplasms; Primary site: Breast. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0bbe1b04-f582-453c-9070-7aafc07912fe

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1971; Vital status: Dead; Days to death: 393 days (1.1 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Metaplastic carcinoma, NOS: ICD-O-3 morphology code: 8575/3; ICD-10 code: C50.912; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Classification of tumor: primary; Age at diagnosis: 46.9 years (17,140 days); AJCC staging edition: 8th; AJCC clinical stage: Stage IIB; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Prior malignancy: no; Prior treatment: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin Hydrochloride; Treatment intent type: Neoadjuvant; Regimen or line of therapy: dose-dense AC; Days to treatment start: 40 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Neoadjuvant; Days to treatment start: 40 days.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 125 days.
   Treatment given: Treatment type: Radiation, Intensity-Modulated Radiotherapy; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 212 days; Days to treatment end: 236 days.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Everolimus; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 316 days.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Exemestane; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 316 days.
   Treatment given: Treatment type: Hormone Therapy; Treatment intent type: Adjuvant; Initial disease status: Residual Disease.
   Recorded as not given: adjuvant Chemotherapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; neoadjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 340 days; Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contacts recording only the day: day 0, day 200.

Molecular and laboratory tests
- ERBB2 (IHC): Negative.
- ESR1 (IHC): 3; Specialized molecular test: Allred score.
- PGR (IHC): Negative.

Other clinical attributes
- Day 0: Menopause status: Premenopausal.
- Timepoint category: Initial Diagnosis; Weight: 58.1 kg; Height: 170.2 cm; BMI: 20.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0366-C50-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0366-C50-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 20; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 80; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-CSHL-0366-C50-01A-01-S1-HE: Section location: Top; Percent tumor cells: 30; Percent tumor nuclei: 40; Percent normal cells: 50; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-CSHL-0366-C50-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-CSHL-0366-C50-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
- Sample HCM-CSHL-0366-C50-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
